Somatic mutation profile of tumor specimen MMRF_1068_1_BM_CD138pos (aliquot MMRF_1068_1_BM_CD138pos_T2_TSE61_K02705) from MMRF case MMRF_1068, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,303 days).
Specimen MMRF_1068_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f208c522-27dc-4bb8-b735-1e3aa2692aff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1068_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1068_1_PB_Whole_C1_TSE61_K02712; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1df5ef4-f434-43dd-af46-3b212acdb288

The open-access MAF lists 126 somatic variants for this specimen: 45 protein-altering or splice-affecting, 20 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 40, Missense Mutation 34, Silent 20, 5'UTR 6, RNA 5, Nonsense Mutation 5, 5'Flank 5, Intron 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.9105C>A p.C3035* (on ENST00000297405 / NM_001363185.1; = p.C2866* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 46/88 reads (52%) | catalogued as COSV52093518; called by muse, mutect2, varscan2
- CSNK2A1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104372005; called by muse, mutect2, varscan2
- EFL1 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 125/206 reads (61%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs777187990, COSV51602832, COSV51608771; called by muse, mutect2, varscan2
- FHAD1 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs983356427; called by muse, mutect2, varscan2
- GATC | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs758566605; called by muse, mutect2, varscan2
- IGSF9B | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs369321654; called by muse, mutect2, varscan2
- KLHL4 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 43/51 reads (84%) | catalogued as rs1357787545; called by muse, mutect2, varscan2
- MKRN3 | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 223/384 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180324511, COSV58811586; called by muse, mutect2, varscan2
- MUC5B | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1049302560, COSV71595941; called by muse, mutect2, varscan2
- NCOR2 | c.4847G>A p.R1616Q | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs776321587, COSV62292748; called by muse, mutect2, varscan2
- PSMA8 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs777581252; called by muse, mutect2, varscan2
- RANBP6 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 20/161 reads (12%) | catalogued as COSV99424500; called by muse, mutect2, varscan2
- RERGL | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.602); catalogued as COSV57461547; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- TRIM40 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as rs774283475; called by muse, mutect2, varscan2
- UNC5D | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201950756; called by muse, mutect2, varscan2
- URB1 | c.2312C>T p.T771M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs867683172; called by muse, mutect2, varscan2
- ZNF629 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52697165; called by muse, mutect2, varscan2
- ACOT6 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD11 | c.7375del p.T2459Rfs*32 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- BBOF1 | c.916T>C p.F306L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2
- CCNB1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- CFAP36 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CHRM3 | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTTNBP2 | c.2935dup p.I979Nfs*2 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- DAOA | c.45-6T>G | Splice Region (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- DLD | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.47); called by muse, mutect2
- HGF | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HSD17B2 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | called by muse, varscan2
- IRX2 | c.1400T>A p.V467D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- KIR3DL3 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.844); called by muse, mutect2
- KLHL6 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 116/166 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAD2L1 | c.113A>C p.Y38S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MEFV | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV3 | c.1108G>T p.V370F | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NUP133 | c.1532_1545del p.E511Gfs*3 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by pindel, varscan2
- PPIP5K2 | c.129del p.I44Lfs*17 | Frame Shift Del (DEL) | VAF 6/75 reads (8%) | called by mutect2, pindel
- PRKD2 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SYCP2L | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TENT5C | c.125dup p.T43Nfs*67 | Frame Shift Ins (INS) | VAF 14/103 reads (14%) | called by mutect2, pindel, varscan2
- TENT5C | c.412T>C p.Y138H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- U2AF2 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2
- ZNF292 | c.6033G>A p.M2011I | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ZNF732 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRF4 | c.831G>A p.R277= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- CACNA2D4 | c.2607G>A p.T869= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs999546293; called by muse, mutect2
- CGNL1 | c.861C>T p.V287= | Silent (SNP) | VAF 59/176 reads (34%) | catalogued as rs1325861845; called by muse, mutect2, varscan2
- CRACDL | c.2229C>T p.S743= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- EPHB3 | c.1329C>T p.A443= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs763706707; called by muse, mutect2, varscan2
- HTR1D | c.795G>A p.S265= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs758930213, COSV58449819; called by muse, mutect2, varscan2
- MAP3K9 | c.2157G>A p.E719= (on ENST00000554752 / NM_001284230.1; = p.E733= on NM_033141.4) | Silent (SNP) | VAF 38/80 reads (48%) | called by muse, mutect2, varscan2
- MIDN | c.357A>G p.Q119= | Silent (SNP) | VAF 44/173 reads (25%) | catalogued as rs1421786867; called by muse, mutect2, varscan2
- NRG1 | c.658A>C p.R220= | Silent (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- OR1S2 | c.810C>T p.G270= | Silent (SNP) | VAF 218/309 reads (71%) | catalogued as rs567196604, COSV100224165, COSV56919868; called by muse, mutect2, varscan2
- OR4X2 | c.690C>T p.S230= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as COSV56584780; called by muse, mutect2, varscan2
- PGR | c.939C>T p.H313= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- RASA4 | c.903G>A p.E301= | Silent (SNP) | VAF 12/51 reads (24%) | called by mutect2, varscan2
- SLC25A41 | c.312G>A p.A104= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs370366254, COSV51192370; called by muse, mutect2, varscan2
- SLC2A10 | c.480C>G p.T160= | Silent (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- SLC39A10 | c.2277C>T p.I759= | Silent (SNP) | VAF 58/144 reads (40%) | called by muse, mutect2, varscan2
- SNX20 | c.168C>T p.T56= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1435553948; called by muse, mutect2, varscan2
- SPOCK2 | c.1242A>G p.A414= | Silent (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
- TENT5C | c.411A>G p.A137= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs760319061; called by muse, mutect2, varscan2
- TYRO3 | c.1317C>T p.A439= | Silent (SNP) | VAF 117/251 reads (47%) | catalogued as rs776201984; called by muse, mutect2, varscan2
- AC008040.1 | n.250-5265A>G | Intron (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ADAM10 | c.*1183T>C | 3'UTR (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2
- ANGPT1 | c.*380A>C | 3'UTR (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2, varscan2
- ANKHD1 | c.*176T>G | 3'UTR (SNP) | VAF 57/88 reads (65%) | called by muse, mutect2, varscan2
- AP000944.2 | chr11:65423142 G>C | 5'Flank (SNP) | VAF 108/182 reads (59%) | called by muse, varscan2
- AP000944.2 | n.66G>A | RNA (SNP) | VAF 82/124 reads (66%) | called by muse, mutect2, varscan2
- AP000944.4 | n.8C>T | RNA (SNP) | VAF 38/112 reads (34%) | called by muse, varscan2
- AP1G1 | c.*3257G>A | 3'UTR (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- ATL2 | c.*573C>A | 3'UTR (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- BCLAF1 | c.*895A>G | 3'UTR (SNP) | VAF 68/119 reads (57%) | catalogued as rs1177607226; called by muse, mutect2, varscan2
- C10orf88 | c.*961T>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- C10orf90 | c.*588A>G | 3'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- CBX5 | c.*7360T>G | 3'UTR (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- CGB3 | c.-157T>C | 5'UTR (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2
- CRB1 | c.*210dup | 3'UTR (INS) | VAF 50/98 reads (51%) | catalogued as rs1558168940; called by mutect2, varscan2
- CXCL6 | c.*39T>A | 3'UTR (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- DACH2 | c.*87T>A | 3'UTR (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100912995; called by muse, mutect2, varscan2
- FAM199X | c.*1282T>C | 3'UTR (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- GLYCAM1 | n.660A>C | RNA (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2
- GOLGA8A | chr15:34400751 C>T | 3'Flank (SNP) | VAF 18/241 reads (7%) | catalogued as rs1388017718; called by muse, mutect2
- GPC6 | c.-113G>A | 5'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- GVINP1 | n.4632A>G | RNA (SNP) | VAF 30/150 reads (20%) | catalogued as rs756822001; called by muse, mutect2, varscan2
- HDAC7 | c.-99+647del | Intron (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- HMGA1 | c.*14C>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- IGBP1 | c.-450G>A | 5'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- IGHD3-3 | chr14:105918313 C>T | 5'Flank (SNP) | VAF 44/46 reads (96%) | called by muse, varscan2
- IGHD3-3 | chr14:105918361 T>A | 5'Flank (SNP) | VAF 42/43 reads (98%) | called by muse, varscan2
- IGHD3-3 | chr14:105918449 C>T | 5'Flank (SNP) | VAF 28/28 reads (100%) | called by muse, varscan2
- IGHD3-3 | chr14:105918813 T>C | 5'Flank (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+859C>T | Intron (SNP) | VAF 55/165 reads (33%) | catalogued as rs759951888; called by muse, mutect2, varscan2
- KCTD12 | c.*1148_*1155del | 3'UTR (DEL) | VAF 10/68 reads (15%) | called by mutect2, pindel, varscan2
- KLHL1 | c.-555G>T | 5'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- LCP1 | c.*1087T>C | 3'UTR (SNP) | VAF 62/105 reads (59%) | called by muse, mutect2, varscan2
- MAST4 | c.*1221C>A | 3'UTR (SNP) | VAF 119/235 reads (51%) | called by muse, mutect2, varscan2
- MYO1E | c.-92C>G | 5'UTR (SNP) | VAF 54/96 reads (56%) | catalogued as rs528359750; called by muse, mutect2, varscan2
- NRCAM | c.*529G>C | 3'UTR (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- NUDT3 | c.*95C>T | 3'UTR (SNP) | VAF 9/93 reads (10%) | catalogued as rs1239332905; called by muse, mutect2
- OR2L1P | n.206A>G | RNA (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- PDGFB | c.*1376A>T | 3'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- PEX13 | c.*1705T>G | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- PI15 | c.*2462T>G | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- PLPPR1 | c.-352C>T | 5'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- PRKAA2 | c.*3605A>C | 3'UTR (SNP) | VAF 45/99 reads (45%) | called by muse, mutect2, varscan2
- RNF180 | c.*1378A>C | 3'UTR (SNP) | VAF 110/196 reads (56%) | called by muse, mutect2, varscan2
- RNF180 | c.*1880A>G | 3'UTR (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- RNF180 | c.*1981A>G | 3'UTR (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- RSBN1 | c.*2440del | 3'UTR (DEL) | VAF 35/87 reads (40%) | called by pindel, varscan2*
- SEMA3D | c.*2838A>C | 3'UTR (SNP) | VAF 84/113 reads (74%) | called by muse, mutect2, varscan2
- SIAH2 | c.*778A>G | 3'UTR (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- SLC15A4 | c.842+571T>C | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- SLC6A7 | c.*313G>T | 3'UTR (SNP) | VAF 25/185 reads (14%) | called by muse, mutect2, varscan2
- SPATA18 | c.*232G>T | 3'UTR (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- TAOK3 | c.*472T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs973032792; called by muse, mutect2, varscan2
- TMEM143 | c.*195C>A | 3'UTR (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- TMEM47 | c.*892A>C | 3'UTR (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- TNRC6C | c.*1575G>C | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, varscan2
- UNC13C | c.*1270T>C | 3'UTR (SNP) | VAF 57/174 reads (33%) | called by muse, mutect2, varscan2
- VPS4B | c.*1633G>A | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- WSCD2 | c.*1685C>A | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- ZBTB41 | c.*3874T>C | 3'UTR (SNP) | VAF 58/145 reads (40%) | called by muse, mutect2, varscan2
- ZNF32 | c.*18A>C | 3'UTR (SNP) | VAF 59/111 reads (53%) | catalogued as COSV100986499; called by muse, mutect2, varscan2
